Somatic mutation profile of tumor specimen TCGA-B6-A0RL-01A (aliquot TCGA-B6-A0RL-01A-11D-A099-09) from TCGA case TCGA-B6-A0RL, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 60.9 years (22,238 days).
Specimen TCGA-B6-A0RL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 956058fb-fbd0-442f-8643-e7963b134398.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0RL-10A (Blood Derived Normal), aliquot TCGA-B6-A0RL-10A-01D-A099-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/198acf97-4e10-404d-8e7a-3a8aa6068edd

The open-access MAF lists 59 somatic variants for this specimen: 45 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 13, Nonsense Mutation 3, Frame Shift Del 2, Translation Start Site 1, Frame Shift Ins 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.7328G>A p.R2443Q | Missense Mutation (SNP) | VAF 72/91 reads (79%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as rs587782310, COSV53726442; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AGL | c.3533C>T p.P1178L | Missense Mutation (SNP) | VAF 95/210 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.398); catalogued as COSV99649967; called by muse, mutect2, varscan2
- AKT3 | c.1124C>A p.S375* | Nonsense Mutation (SNP) | VAF 55/239 reads (23%) | catalogued as COSV99796464; called by muse, mutect2, varscan2
- ANO3 | c.116G>A p.C39Y | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99885361; called by muse, mutect2, varscan2
- ARHGAP21 | c.3338A>G p.D1113G | Missense Mutation (SNP) | VAF 11/185 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs1355682151, COSV100256613, COSV100256760; called by muse, mutect2
- CACNA1C | c.5065G>A p.A1689T | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as rs368700869; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC116 | c.1369C>G p.L457V | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99489484; called by muse, mutect2, varscan2
- CHGB | c.1311G>T p.E437D | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.107); catalogued as COSV66759967, COSV66761824; called by muse, mutect2, varscan2
- CNTN3 | c.1985T>C p.V662A | Missense Mutation (SNP) | VAF 91/234 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.168); catalogued as rs147790729; called by muse, mutect2, varscan2
- COL18A1 | c.3919G>A p.G1307R (on ENST00000359759 / NM_130444.3; = p.G1072R on NM_030582.4) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs576719084, COSV60588076; called by muse, mutect2, varscan2
- CUL4B | c.2569A>G p.I857V | Missense Mutation (SNP) | VAF 11/324 reads (3%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.811); catalogued as COSV100341117, COSV60687148; called by muse, mutect2
- DLGAP2 | c.2450C>T p.A817V | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.994); catalogued as rs774180756, COSV70097614; called by muse, mutect2, varscan2
- EP300 | c.2299C>T p.Q767* | Nonsense Mutation (SNP) | VAF 56/72 reads (78%) | catalogued as COSV54328436; called by muse, mutect2, varscan2
- ESRRG | c.1077G>A p.M359I | Missense Mutation (SNP) | VAF 90/250 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV100753791; called by muse, mutect2, varscan2
- F2 | c.1390G>T p.A464S | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100319668; called by muse, mutect2, varscan2
- FBXL19 | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 49/82 reads (60%) | SIFT tolerated, low confidence (0.83); PolyPhen probably damaging (0.98); catalogued as rs1262416294, COSV100609337; called by muse, mutect2, varscan2
- GBP2 | c.1432C>T p.Q478* | Nonsense Mutation (SNP) | VAF 30/236 reads (13%) | catalogued as rs1189186653, COSV100975426; called by muse, mutect2, varscan2
- GRAMD1C | c.1669C>G p.L557V | Missense Mutation (SNP) | VAF 81/200 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV100822818, COSV100822978; called by muse, mutect2, varscan2
- GSPT1 | c.314C>T p.T105M (on ENST00000420576 / NM_001130007.2; = p.T243M on NM_002094.4) | Missense Mutation (SNP) | VAF 104/386 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1356536374, COSV70453217; called by muse, mutect2, varscan2
- GTF2H1 | c.1584G>A p.M528I | Missense Mutation (SNP) | VAF 53/280 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.421); catalogued as rs751551035, COSV99786603; called by muse, mutect2, varscan2
- HGFAC | c.1562G>A p.C521Y | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101237784; called by muse, mutect2, varscan2
- HGS | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1474180492, COSV61270535; called by muse, mutect2, varscan2
- MKI67 | c.1022A>G p.E341G | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT tolerated (0.09); PolyPhen benign (0.093); catalogued as COSV100896941; called by muse, mutect2, varscan2
- NOP16 | c.329C>T p.T110I | Missense Mutation (SNP) | VAF 86/214 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.794); catalogued as COSV99220963; called by muse, mutect2, varscan2
- OR52D1 | c.698C>A p.S233Y | Missense Mutation (SNP) | VAF 19/321 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100495321, COSV59487307; called by muse, mutect2
- PAEP | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs570771664, COSV99479001; called by muse, mutect2, varscan2
- PAMR1 | c.2020C>T p.P674S (on ENST00000619888 / NM_001001991.3; = p.P691S on NM_015430.4) | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.949); catalogued as rs1367705145, COSV53514615, COSV99553191; called by muse, mutect2, varscan2
- PCDHGB6 | c.1426G>A p.A476T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367728235; called by muse, mutect2, varscan2
- PPARGC1A | c.695G>T p.S232I | Missense Mutation (SNP) | VAF 181/920 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); catalogued as COSV99338558; called by muse, mutect2, varscan2
- PQBP1 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as COSV99504540; called by muse, varscan2
- PQBP1 | c.293-1G>C p.X98_splice | Splice Site (SNP) | VAF 11/78 reads (14%) | catalogued as COSV99504541; called by muse, mutect2, varscan2
- PRKCG | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV54730220, COSV99668594; called by muse, mutect2, varscan2
- RBM6 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 39/104 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.746); catalogued as COSV99805863; called by muse, mutect2, varscan2
- SEMG1 | c.1188G>T p.E396D | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.132); catalogued as COSV99725538; called by muse, mutect2
- SH3RF2 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100768002; called by muse, mutect2, varscan2
- SHROOM2 | c.4769G>A p.R1590Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773254075, COSV101099017; called by mutect2, varscan2
- THOC1 | c.419G>A p.C140Y | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99863594; called by muse, mutect2, varscan2
- TRAK2 | c.1116A>C p.E372D | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100217104; called by muse, mutect2, varscan2
- TRIOBP | c.2252G>A p.R751Q | Missense Mutation (SNP) | VAF 319/447 reads (71%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs1324254346, COSV60374871; called by muse, mutect2, varscan2
- UNC5D | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 28/333 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as COSV54813878; called by muse, mutect2
- VBP1 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.499); catalogued as COSV99660765; called by muse, mutect2, varscan2
- CHAC1 | c.647A>C p.E216A | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2
- DHRS9 | c.610del p.I204Lfs*14 | Frame Shift Del (DEL) | VAF 21/195 reads (11%) | called by mutect2, pindel, varscan2
- KIF21A | c.387dup p.H130Tfs*5 | Frame Shift Ins (INS) | VAF 32/92 reads (35%) | called by mutect2, varscan2
- SLC6A18 | c.461del p.G154Afs*5 | Frame Shift Del (DEL) | VAF 34/115 reads (30%) | called by mutect2, pindel, varscan2
- CAPZA2 | c.753G>A p.S251= | Silent (SNP) | VAF 63/132 reads (48%) | catalogued as rs778724933, COSV100753993; called by muse, mutect2, varscan2
- CHCHD7 | c.228C>T p.I76= (on ENST00000355315 / NM_001011671.3; = p.I88= on NM_024300.4) | Silent (SNP) | VAF 86/196 reads (44%) | catalogued as COSV100374718; called by muse, mutect2, varscan2
- DGKQ | c.2133C>T p.L711= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs772756868, COSV99298186; called by muse, mutect2, varscan2
- HCN4 | c.924C>T p.I308= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as rs1256500370, COSV56082790, COSV56086455; called by muse, mutect2, varscan2
- MTHFD2L | c.891G>A p.V297= (on ENST00000395759 / NM_001144978.2; = p.V239= on NM_001004346.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 71/158 reads (45%) | catalogued as COSV100306328; called by muse, mutect2, varscan2
- NLRP6 | c.2544G>T p.L848= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV100381153; called by mutect2, varscan2
- PHF8 | c.114C>T p.A38= (on ENST00000357988 / NM_001184896.1; = p.A2= on NM_015107.3) | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as rs782702543, COSV100154754; called by muse, mutect2, varscan2
- PLVAP | c.1116G>A p.A372= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as rs535383500, COSV53083209, COSV53086717; called by muse, mutect2, varscan2
- RNF130 | c.1029C>T p.L343= | Silent (SNP) | VAF 14/166 reads (8%) | catalogued as rs150207439, COSV56153997; called by muse, mutect2
- SIDT1 | c.510G>A p.Q170= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV99334606; called by muse, mutect2, varscan2
- SLC4A3 | c.714C>T p.G238= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as COSV99813160; called by muse, mutect2, varscan2
- SLTM | c.1941C>G p.R647= | Silent (SNP) | VAF 68/128 reads (53%) | catalogued as COSV99989380; called by muse, mutect2, varscan2
- YIPF7 | c.615C>T p.S205= | Silent (SNP) | VAF 39/75 reads (52%) | catalogued as rs370783649; called by muse, mutect2, varscan2
- CLCN5 | c.17-38801C>T | Intron (SNP) | VAF 14/125 reads (11%) | catalogued as COSV101067315; called by muse, mutect2, varscan2
